Somatic mutation profile of tumor specimen 0DUUQ1 from CCDI case PBCLPI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.9 years (7,270 days).
Specimen 0DUUQ1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40b643c7-d553-4822-b166-01e56341f672.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUUPN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8909f14d-c38f-40bf-b9b1-9075c5187a2d

The open-access MAF lists 54 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Intron 8, 3'UTR 7, Silent 7, Nonsense Mutation 4, 5'UTR 3, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC1H1 | c.4532C>T p.P1511L | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327664377, COSV64134818; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 146/296 reads (49%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 138/294 reads (47%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 102/225 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by muse, varscan2
- ADAMTS12 | c.4174G>A p.V1392M | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs777630888, COSV100711434, COSV61275688; called by muse, varscan2
- APOBEC1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762259232; called by muse, varscan2
- CCDC88C | c.4337C>T p.A1446V | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.6); PolyPhen benign (0.054); catalogued as rs759055200, COSV100484991; called by muse, varscan2
- COL22A1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs764763126, COSV57327075; called by muse, varscan2
- CRAMP1 | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV51961506; called by muse, varscan2
- GIMAP7 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as rs759238652, COSV57958772; called by muse, varscan2
- GPRIN2 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1555019281, COSV100966278; called by muse, varscan2
- LRFN5 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53246766; called by muse, varscan2
- MAEL | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 244/400 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV63305780; called by muse, varscan2
- TP63 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 188/288 reads (65%) | catalogued as rs147340040; ClinVar: uncertain significance; called by muse, varscan2
- TTLL6 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs867190204; called by muse, varscan2
- ATRX | c.6541A>C p.T2181P | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, varscan2
- CBX6 | c.921G>A p.W307* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | called by muse, varscan2
- DNAH2 | c.9050C>T p.T3017I | Missense Mutation (SNP) | VAF 103/266 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- DYNC2I1 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 110/262 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- MAGEC3 | c.1216G>C p.G406R | Missense Mutation (SNP) | VAF 98/169 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, varscan2
- MUC3A | c.8152A>T p.S2718C | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, varscan2
- SMAP2 | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 104/271 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- SNRNP200 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- SOAT2 | c.1138-1G>T p.X380_splice | Splice Site (SNP) | VAF 76/186 reads (41%) | called by muse, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, varscan2
- TSHZ1 | c.2489C>G p.S830* (on ENST00000580243 / NM_001308210.2; = p.S785* on NM_005786.6) | Nonsense Mutation (SNP) | VAF 94/232 reads (41%) | called by muse, varscan2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- ZNF711 | c.1879G>T p.G627C | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- APOBEC2 | c.525A>G p.K175= | Silent (SNP) | VAF 82/189 reads (43%) | called by muse, varscan2
- CARD10 | c.1815G>A p.R605= | Silent (SNP) | VAF 40/108 reads (37%) | called by muse, varscan2
- CD180 | c.681G>A p.L227= | Silent (SNP) | VAF 21/206 reads (10%) | catalogued as rs1192077978, COSV56518622; called by muse, varscan2
- KCNA4 | c.177G>T p.G59= | Silent (SNP) | VAF 62/111 reads (56%) | called by muse, varscan2
- MCM8 | c.2334A>G p.R778= | Silent (SNP) | VAF 58/174 reads (33%) | called by muse, varscan2
- RHOXF2 | c.336G>A p.K112= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs782742882; called by muse, varscan2
- UNC13A | c.1179C>T p.T393= | Silent (SNP) | VAF 77/172 reads (45%) | catalogued as rs370189061; called by muse, varscan2
- ARHGEF12 | c.2226-98A>C | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, varscan2
- CBX3 | c.*28T>A | 3'UTR (SNP) | VAF 24/134 reads (18%) | catalogued as COSV100523016; called by muse, varscan2
- CLDN16 | chr3:190388144 G>T | 5'Flank (SNP) | VAF 98/317 reads (31%) | called by muse, varscan2
- COPS2 | c.715+50T>A | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 27/145 reads (19%) | called by muse, varscan2
- DARS1 | c.*51C>T | 3'UTR (SNP) | VAF 12/65 reads (18%) | catalogued as rs1250131780; called by muse, varscan2
- EFNB1 | c.*42G>T | 3'UTR (SNP) | VAF 12/34 reads (35%) | called by muse, varscan2
- FCHO2 | c.1173+13A>G | Intron (SNP) | VAF 8/51 reads (16%) | called by muse, varscan2
- IGFN1 | c.1241+2136G>A | Intron (SNP) | VAF 104/166 reads (63%) | catalogued as rs772053968; called by muse, varscan2
- LARS2 | c.*1037C>T | 3'UTR (SNP) | VAF 133/458 reads (29%) | catalogued as rs750197363, COSV55526928; called by muse, varscan2
- LINC02223 | n.217+44256A>T | Intron (SNP) | VAF 8/76 reads (11%) | called by muse, varscan2
- MUC19 | c.325-39A>G | Intron (SNP) | VAF 16/67 reads (24%) | catalogued as rs1344620976; called by muse, varscan2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 16/106 reads (15%) | catalogued as rs926414386, COSV100695372; called by muse, varscan2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 16/104 reads (15%) | called by muse, varscan2
- OR5V1 | c.*6A>T | 3'UTR (SNP) | VAF 12/70 reads (17%) | called by muse, varscan2
- OR5V1 | c.*5C>G | 3'UTR (SNP) | VAF 12/72 reads (17%) | called by muse, varscan2
- PLA2G1B | c.35-65A>T | Intron (SNP) | VAF 20/42 reads (48%) | called by muse, varscan2
- RNF113A | c.-23G>T | 5'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, varscan2
- TTC7B | c.1237-23G>A | Intron (SNP) | VAF 30/63 reads (48%) | catalogued as rs964790058; called by muse, varscan2
